Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F1, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F1-01A (Primary Tumor).

ICD-0-3
Melanoma, epithelioid cell
8771/3
Site ~~C69.3~~
Choroid C69.3
path
Uveal tract C69.4
JW 2/16/14

Enucleation of the right eye

Macroscopy

The eyeball measures 22 mm in diameter with a segment of optic nerve of 8 mm.

At the section, a pigmented blackish nodule measuring 17X12 mm. The specimen has been included entirely.

Microscopy

The tumor observed macroscopically presents the histological aspect of an uveal melanoma. This tumor is composed mainly of epithelioid cells, more rarely fusiform (<1%). The cell atypias are severe. The pigmented load is mild. The mitotic activity is low (2 mitosis per 10 HPF). There is a focal tumor extension on the inner part of the sclera, without extra-scleral exteriorisation. The optic nerve and the anterior chamber are free of tumor.

Conclusion

Uveal melanoma of the right eye.

Tumor size: 17 mm main line.

Focal tumor infiltration of the inner part of the sclera, without extra-scleral extension.

Optic nerve free of tumor.

Crite. In	Yes	No
Qual/Synchronou: Primary Noted		/

Source: NCI Genomic Data Commons file 80fe270d-c288-4ea7-a7d8-c309afd2ebdb (TCGA-V4-A9F1.B34668F2-C885-426D-9DDC-C310C8DF9616.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).